Somatic mutation profile of tumor specimen TARGET-10-PARBLS-09A (aliquot TARGET-10-PARBLS-09A-01D) from TARGET case TARGET-10-PARBLS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,013 days).
Specimen TARGET-10-PARBLS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d118ff8-d4d3-490b-b85f-13a59e059339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBLS-10A (Blood Derived Normal), aliquot TARGET-10-PARBLS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7420117-dacb-4249-a99d-b9a17ed60d11

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP43 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV53381219; called by muse, mutect2, varscan2
- DSCAM | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs541446344; called by muse, mutect2, varscan2
- FER | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229844751; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- TTBK1 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780428200; called by muse, mutect2, varscan2
- KMT2D | c.11299C>T p.Q3767* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- PAX5 | c.602_603del p.E201Gfs*41 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2*
- SLITRK2 | c.2186A>G p.E729G | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUNX2 | c.1413G>A p.P471= (on ENST00000371438; = p.P449= on NM_001015051.3) | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as rs114897742; called by muse, mutect2, varscan2
- TAF7L | c.141C>T p.A47= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs757605410; called by muse, mutect2, varscan2
